Somatic mutation profile of tumor specimen MP2PRT-PAVHAP-TMP1-A (aliquot MP2PRT-PAVHAP-TMP1-A-1-0-D-A80L-36) from MP2PRT case MP2PRT-PAVHAP, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,615 days).
Specimen MP2PRT-PAVHAP-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a94ac83f-d313-4608-9629-ccf8cb07c731.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAVHAP-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAVHAP-NB1-A-1-0-D-A80L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f0f572e-4bbd-4b53-90ce-57f1cdc439e2

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 4 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Silent 4, Intron 1, Frame Shift Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APOC2 | c.196G>A p.A66T | Missense Mutation (SNP) | VAF 82/217 reads (38%) | SIFT tolerated (0.87); PolyPhen benign (0.003); catalogued as rs770092327; called by muse, mutect2, varscan2
- ARHGEF11 | c.2191C>T p.R731W | Missense Mutation (SNP) | VAF 38/290 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1017809905, COSV59357611; called by muse, mutect2, varscan2
- CNTNAP3 | c.2944del p.V982Sfs*29 | Frame Shift Del (DEL) | VAF 116/283 reads (41%) | catalogued as rs763585044, COSV52668218; called by mutect2, varscan2
- CREBBP | c.4463C>A p.P1488Q | Missense Mutation (SNP) | VAF 180/420 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52116625, COSV52132987, COSV52135343; called by muse, mutect2, varscan2
- DENND3 | c.1967G>A p.R656Q | Missense Mutation (SNP) | VAF 32/532 reads (6%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.952); catalogued as rs753853397; called by muse, mutect2
- HR | c.2506C>T p.R836W | Missense Mutation (SNP) | VAF 221/687 reads (32%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.549); catalogued as rs769276005; called by muse, mutect2, varscan2
- KRT85 | c.796G>A p.V266I | Missense Mutation (SNP) | VAF 21/238 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.009); catalogued as rs768562539, COSV57738497; called by muse, mutect2
- PDYN | c.73C>T p.R25W | Missense Mutation (SNP) | VAF 91/206 reads (44%) | SIFT tolerated (0.17); PolyPhen benign (0); catalogued as rs1028619685; called by muse, mutect2, varscan2
- RIMBP2 | c.355C>T p.R119W | Missense Mutation (SNP) | VAF 67/334 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.336); catalogued as rs750761572, COSV55474537, COSV99900415; called by muse, mutect2, varscan2
- PKN1 | c.2478_2479insTC p.I827Sfs*21 | Frame Shift Ins (INS) | VAF 34/287 reads (12%) | called by mutect2, pindel, varscan2
- CACNA1I | c.1182C>T p.L394= | Silent (SNP) | VAF 104/373 reads (28%) | catalogued as rs1200610839; called by muse, mutect2, varscan2
- CRISP1 | c.402G>A p.T134= | Silent (SNP) | VAF 40/521 reads (8%) | catalogued as rs762995653, COSV59995815; called by muse, mutect2
- HAS2 | c.141A>G p.G47= | Silent (SNP) | VAF 125/423 reads (30%) | called by muse, mutect2, varscan2
- TRIM67 | c.270C>T p.G90= | Silent (SNP) | VAF 268/606 reads (44%) | catalogued as rs1415874601, COSV64160596; called by muse, mutect2, varscan2
- NKX6-3 | c.553-601_553-598dup | Intron (INS) | VAF 173/612 reads (28%) | called by mutect2, pindel, varscan2
